Surgical pathology report (de-identified scan), TCGA case TCGA-XX-A89A, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Spectrum Health, specimen TCGA-XX-A89A-01A (Primary Tumor).

[page 1 of 2]
Research Gross Description

Research Dx

Left breast (1945 g), mastectomy:
Invasive lobular carcinoma.
7 regional lymph nodes, negative for malignancy (0/7)
Tumor site: Upper outer quadrant (2-3:00)
Tumor size: Between 7 and 9 cm
Histopathologic type: Invasive lobular carcinoma
Histopathologic grade (Nottingham): 2
Mitotic count: Low proliferative rate
Pathologic tumor stage: pT3
Margin status:

Distance of carcinoma from margins:

Superior: 0.8 cm
Inferior: At least 1 cm
Medial: Greater than 2 cm
Lateral: Greater than 2 cm
Anterior: 1 cm
Posterior: Greater than 1 cm

Associated in situ carcinoma:

Type: Lobular carcinoma in situ (rare focus)
Extensive (>25% of total tumor): No
Separate (extra-tumoral) foci away from main lesion: Not identified

Peritumoral angiolymphatic invasion: Not identified

Dermal angiolymphatic invasion: Not identified

Estrogen receptor: Positive (70 % of tumor cell nuclei staining moderately to strongly)
Progesterone receptor: Positive (70 % of tumor cell nuclei staining moderately to strongly)
HER-2/neu (ERBB2): Negative (score 0)
Duration of fixation in 10% NBF: 12 hours 24 minutes
Appropriate internal and external controls: Yes
Standard assay conditions met? Yes

Pathologic lymph node stage: pN0 (including sentinel): No regional lymph node metastasis

Number of nodes positive for metastasis/total number nodes sampled: 0/11

Maximum diameter of largest lymph node metastasis: Not applicable

Extranodal extension by tumor: Not applicable

Distant metastasis: M-not applicable

Additional pathologic findings: Fibrocystic change and usual ductal hyperplasia; seborrheic keratosis

TNM descriptors (if applicable):

AJCC Staging (7th Edition): pT3 pN0 M-not applicable

Research QC

T1 Tumor:

50% tumor nuclei
0% necrosis
50% normal

Normal:

100% fibroadipose

ICD-O-3
Carcinoma, infiltrating lobular NOS
Site ⑤ Breast NOS 8520/3
⑤ Breast NOS C50.9
⑤ Breast, upper-outer quadrant C50.4
JW 11/22/13

[page 2 of 2]
T2
50% tumor nuclei
0% necrosis
50% normal fibrous tissue and fat. minimal normal breast

T3
70% tumor nuclei
0% necrosis
30% normal

T4
50% tumor nuclei
0% necrosis
50% normal fat, could prob be trimmed

Research Specimen

-

Specimen Process Time

Blood draw time
Plasma frozen time:
Serum frozen time
Buffy coat frozen time:

Cold ischemia start time:
Formalin fixation start time:
Total cold ischemia time:
Formalin fixation stopped time
Total formalin fixation time:

Specimen Weight

Cryovials x 8
Normal x 4 - 1.) 335 mg 2.) 321 mg 3.) 408 mg 4.) 447 mg
Tumor x 4 - 1.) 351 mg 2.) 357 mg 3.) 252 mg 4.) 322 mg

Specimen Size

Plasma x 3
Serum x 2
Buffy coat x 1

Cryovials x 8
Normal x 4
Tumor x 4

FFPE x 8
Normal x 4
Tumor x 4

Study

Patient Consent

Yes

Reg. Basis Discrepancy		

Source: NCI Genomic Data Commons file 139ee1b1-f575-4a15-9cf2-485dfad41be6 (TCGA-XX-A89A.5D85E578-64B4-4238-922E-802B8ED87800.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).